TARGET case TARGET-30-PANVWD — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/5eda82a4-5deb-55d5-9d94-89567bf261dd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.1 years (749 days); Year of diagnosis: 2005; Days to last follow up: 1,279 days (3.5 years); INSS stage: Stage 4.
